Somatic mutation profile of tumor specimen HTMCP-03-06-02138-01A (aliquot HTMCP-03-06-02138-01A-01D-5099) from CGCI case HTMCP-03-06-02138, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G2.
Specimen HTMCP-03-06-02138-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9b90bdeb-444f-4deb-af2d-20190e0b00ff.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02138-10A (Blood Derived Normal), aliquot HTMCP-03-06-02138-10A-01D-5099; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9dafdb52-b8a5-47d9-a448-997fe77329b5

The open-access MAF lists 64 somatic variants for this specimen: 45 protein-altering or splice-affecting, 16 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 16, Nonsense Mutation 2, RNA 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.235G>C p.E79Q | Missense Mutation (SNP) | VAF 29/138 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519922, COSV67959999, COSV67960008, COSV67960140; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SUGCT | c.514C>T p.R172* | Nonsense Mutation (SNP) | VAF 22/91 reads (24%) | catalogued as rs137852861, CM085300, COSV100000848, COSV59318017; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAMTS12 | c.1693G>A p.A565T | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.671); catalogued as rs369198358, COSV61260706; called by muse, mutect2, varscan2
- ANK1 | c.2284G>A p.E762K | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.124); catalogued as rs771469784; called by muse, mutect2, varscan2
- ATRX | c.3200C>T p.S1067L | Missense Mutation (SNP) | VAF 52/211 reads (25%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as COSV64885504; called by muse, mutect2, varscan2
- CD1E | c.428A>T p.Q143L | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.604); catalogued as rs761807945; called by muse, mutect2, varscan2
- COL7A1 | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs752101927, COSV60396802; called by muse, mutect2, varscan2
- ERICH3 | c.3281A>T p.E1094V | Missense Mutation (SNP) | VAF 64/236 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); catalogued as COSV58604580; called by muse, mutect2, varscan2
- GCN1 | c.2644G>A p.D882N | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.88); PolyPhen benign (0.013); catalogued as rs1566308925; called by muse, mutect2, varscan2
- GPRIN2 | c.1228C>T p.H410Y | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs782386120; called by muse, mutect2, varscan2
- HLA-B | c.701C>T p.P234L | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.242); catalogued as rs74428022; called by muse, mutect2, varscan2
- LIMA1 | c.2031G>T p.E677D | Missense Mutation (SNP) | VAF 99/275 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as COSV57967573; called by muse, mutect2, varscan2
- MYOM2 | c.724G>A p.A242T | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV50761673; called by muse, mutect2, varscan2
- PAPPA2 | c.976C>T p.R326C | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs368485332, COSV62776395; called by muse, mutect2, varscan2
- SETD5 | c.3890C>T p.T1297M | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.09); catalogued as rs777269897, COSV100200603; called by muse, mutect2, varscan2
- SLC9C1 | c.3111G>A p.M1037I | Missense Mutation (SNP) | VAF 30/179 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV59894264; called by muse, mutect2, varscan2
- SOCS6 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.778); catalogued as rs777820754, COSV67546888; called by muse, mutect2, varscan2
- TBC1D23 | c.584C>G p.S195C | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.027); catalogued as rs1181599061; called by muse, mutect2, varscan2
- THOC2 | c.911C>T p.A304V | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs202244860; called by mutect2, varscan2
- TRERF1 | c.2339G>A p.R780H | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.848); catalogued as rs376023255; called by muse, mutect2, varscan2
- TTN | c.23075C>T p.S7692F (on ENST00000591111; = p.S6765F on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/104 reads (43%) | PolyPhen possibly damaging (0.654); catalogued as rs759900757, COSV60185238; called by muse, mutect2, varscan2
- TTN | c.43G>A p.V15I | Missense Mutation (SNP) | VAF 39/91 reads (43%) | PolyPhen benign (0.037); catalogued as rs201857541, COSV60420576; ClinVar: benign / conflicting interpretations of pathogenicity / uncertain significance / likely benign; called by muse, mutect2, varscan2
- AC244197.3 | c.886C>T p.P296S | Missense Mutation (SNP) | VAF 18/259 reads (7%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.474); called by muse, mutect2
- ADNP | c.2293G>A p.E765K | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ARPP21 | c.2281G>A p.G761R | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BRINP1 | c.1816A>G p.N606D | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.441); called by muse, mutect2, varscan2
- COL6A5 | c.6902G>C p.R2301T (on ENST00000312481; = p.R2297T on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/258 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- DAAM1 | c.2486G>C p.R829T | Missense Mutation (SNP) | VAF 11/208 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DIAPH2 | c.2126T>C p.L709S | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- EML5 | c.3995T>A p.I1332N | Missense Mutation (SNP) | VAF 13/150 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.031); called by muse, mutect2
- EVI5 | c.2317G>A p.A773T | Missense Mutation (SNP) | VAF 46/191 reads (24%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FLNB | c.6880A>G p.S2294G | Missense Mutation (SNP) | VAF 18/22 reads (82%) | SIFT tolerated (0.29); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- FRAS1 | c.5251C>A p.Q1751K | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- KNL1 | c.5476G>A p.E1826K (on ENST00000346991 / NM_170589.5; = p.E1800K on NM_144508.5) | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.56); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- LRFN5 | c.1081A>G p.N361D | Missense Mutation (SNP) | VAF 20/248 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MATR3 | c.1219C>T p.R407* | Nonsense Mutation (SNP) | VAF 5/74 reads (7%) | called by muse, mutect2
- NAA25 | c.284C>T p.P95L | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- NRXN3 | c.2125G>T p.V709L (on ENST00000335750 / NM_001330195.2; = p.V336L on NM_004796.6) | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- PDZRN4 | c.2507C>T p.S836F (on ENST00000402685 / NM_001164595.2; = p.S578F on NM_013377.4) | Missense Mutation (SNP) | VAF 23/182 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- RPGR | c.1272G>A p.M424I | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.231); called by mutect2, varscan2
- TENM3 | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- TICAM1 | c.1339G>C p.D447H | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- TTI1 | c.1177G>A p.D393N | Missense Mutation (SNP) | VAF 62/244 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TTN | c.73723G>A p.D24575N (on ENST00000591111; = p.D17151N on NM_003319.4) | Missense Mutation (SNP) | VAF 20/188 reads (11%) | PolyPhen benign (0.234); called by muse, mutect2, varscan2
- VIT | c.1162A>G p.N388D (on ENST00000389975 / NM_001177969.1; = p.N403D on NM_053276.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ADAMTSL1 | c.3156G>A p.T1052= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as rs926704602; called by muse, mutect2, varscan2
- CACNA1D | c.2457G>A p.P819= (on ENST00000350061 / NM_001128840.3; = p.P839= on NM_000720.4) | Silent (SNP) | VAF 27/80 reads (34%) | catalogued as rs141704756; called by muse, mutect2, varscan2
- COL6A5 | c.5160G>A p.Q1720= | Silent (SNP) | VAF 11/118 reads (9%) | catalogued as COSV55216460; called by muse, mutect2, varscan2
- CTNND2 | c.1710G>A p.A570= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as rs765877085; called by mutect2, varscan2
- FAT2 | c.9594G>C p.L3198= | Silent (SNP) | VAF 11/17 reads (65%) | called by muse, mutect2, varscan2
- IGSF9B | c.588A>G p.T196= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as rs1162537878; called by muse, mutect2, varscan2
- MAST1 | c.3732C>T p.P1244= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as rs550879716; called by muse, varscan2
- MTCL1 | c.3168G>A p.Q1056= (on ENST00000306329 / NM_001378206.1; = p.Q737= on NM_015210.4) | Silent (SNP) | VAF 7/43 reads (16%) | called by muse, mutect2, varscan2
- MYO1F | c.1227G>A p.K409= | Silent (SNP) | VAF 11/62 reads (18%) | called by muse, mutect2, varscan2
- NOS2 | c.1008C>T p.Y336= | Silent (SNP) | VAF 28/54 reads (52%) | catalogued as rs201009155; called by muse, mutect2, varscan2
- PCDH17 | c.3126G>A p.A1042= | Silent (SNP) | VAF 58/122 reads (48%) | catalogued as rs534412507, COSV100931621, COSV100931767, COSV64975173; called by muse, mutect2, varscan2
- PCDH19 | c.753G>A p.S251= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV55261453, COSV55273024; called by muse, mutect2, varscan2
- RBBP7 | c.582T>C p.S194= | Silent (SNP) | VAF 20/78 reads (26%) | called by muse, mutect2, varscan2
- RSF1 | c.879G>A p.V293= | Silent (SNP) | VAF 16/117 reads (14%) | called by muse, mutect2, varscan2
- TAS2R46 | c.306C>T p.L102= | Silent (SNP) | VAF 12/255 reads (5%) | catalogued as rs1012865620, COSV67855627; called by muse, mutect2
- TPO | c.2595C>T p.L865= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as rs373215668; called by muse, mutect2, varscan2
- AC008132.1 | n.3245G>A | RNA (SNP) | VAF 42/92 reads (46%) | called by muse, mutect2, varscan2
- MIGA2 | c.1270-107C>T | Intron (SNP) | VAF 10/44 reads (23%) | catalogued as rs1220406252; called by muse, mutect2, varscan2
- MUC19 | n.5277G>A | RNA (SNP) | VAF 29/69 reads (42%) | called by muse, mutect2, varscan2
